Surgical pathology report (de-identified scan), TCGA case TCGA-DY-A1DC, project TCGA-READ (Rectum Adenocarcinoma), tissue source site University Of Michigan, specimen TCGA-DY-A1DC-01A (Primary Tumor).

108-0-3
Adenocarcinoma, NOS 8140/3
Site Code: Recto-sigmoid junction C19-9

1/10/11
JW

(First Tumor)

Tumor Site:	Rectosigmoid Junction
Date of Cancer Sample Procurement:	
Histology:	Adenocarcinoma
Description of other histology:	
Grade:	Moderately Differentiated
Mucinous:	☒ No ☐ Yes ☐ Yes (Focal) ☐ Unknown
Signet Ring Feature:	☒ No ☐ Yes ☐ Yes (Focal) ☐ Unknown
Histologic Heterogeneity:	☐ No ☒ Yes ☐ Unknown
Host Response:	None
Crohn's like reaction	☒ None ☐ Yes ☐ Unknown
Plasma cell rich stroma	☐ No ☐ Yes ☐ Unknown
Growth Pattern:	☐ Expansile ☒ Invasive ☐ Expansile and Invasive ☐ Unknown
Inflammatory Bowel Disease	☒ No ☐ Yes ☐ Unknown
Angiolymphatic Invasion:	☒ No ☐ Yes ☐ Unknown
Mutator Phenotype:	☒ No ☐ Yes ☐ Unknown
Number of Slides	1
Garland Necrosis present:	☐ No ☒ Yes ☐ Yes (Focal) ☐ Unknown
TIL Cells / HPF	6
Pathologist Comment:	focal colitis, probably sec

Source: NCI Genomic Data Commons file 4e598a9a-86c9-4d96-98a5-762d11fe3a38 (TCGA-DY-A1DC.F55AE177-0D13-4120-B2BF-86068D961F6C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).